Somatic mutation profile of tumor specimen 0DDPPS from CCDI case PBBNPF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.4 years (3,429 days).
Specimen 0DDPPS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4f12d04-fde7-4a11-bbac-749206f4c4c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDPPX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/792ce582-cbf5-4572-9dd7-b6f1f061d36c

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 5, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 219/518 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 215/753 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BVES | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 188/327 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58947325; called by muse, mutect2, varscan2
- CCDC168 | c.16003C>T p.R5335W | Missense Mutation (SNP) | VAF 20/692 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs1239147502; called by muse, mutect2
- CPEB1 | c.1229G>A p.R410Q (on ENST00000617958; = p.R350Q on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/662 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.82); catalogued as rs1018099950, COSV99917499; called by muse, mutect2
- CSMD2 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 50/534 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200867038, COSV99585859; called by muse, mutect2
- CSNK1A1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 98/796 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV55792565; called by muse, mutect2, varscan2
- ELOVL2 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 158/267 reads (59%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.767); catalogued as rs554486961, COSV61154096; called by muse, mutect2, varscan2
- GYS1 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 75/818 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs756642679, COSV54401543; called by muse, mutect2
- JADE3 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 94/375 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1355562695, COSV99509937; called by muse, mutect2, varscan2
- LRRK1 | c.3409G>A p.V1137I | Missense Mutation (SNP) | VAF 150/547 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs537781752; called by muse, mutect2, varscan2
- NR4A1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 54/592 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1321725750, COSV99671215; called by muse, mutect2
- OPHN1 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 207/694 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1555988278, COSV62784569; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A43 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs1015167123; called by muse, mutect2
- SPTB | c.4472C>G p.T1491R | Missense Mutation (SNP) | VAF 79/269 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.175); catalogued as COSV67635773; called by muse, mutect2, varscan2
- TEX15 | c.4813C>T p.H1605Y (on ENST00000256246; = p.H1988Y on NM_001350162.2) | Missense Mutation (SNP) | VAF 152/870 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs1356062472; called by muse, mutect2, varscan2
- UBR3 | c.3125G>A p.R1042H | Missense Mutation (SNP) | VAF 147/547 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs756507387; called by muse, mutect2, varscan2
- CARMIL3 | c.1439T>A p.V480D | Missense Mutation (SNP) | VAF 60/489 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- EHMT1 | c.3886G>A p.D1296N | Missense Mutation (SNP) | VAF 31/344 reads (9%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.174); called by muse, mutect2
- HDAC1 | c.290G>A p.G97D | Missense Mutation (SNP) | VAF 116/426 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NR2C2 | c.1313T>C p.M438T (on ENST00000393102; = p.M457T on NM_003298.5) | Missense Mutation (SNP) | VAF 144/492 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- SLC5A8 | c.1262G>T p.G421V | Missense Mutation (SNP) | VAF 146/512 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SSR4 | c.179G>C p.R60T | Missense Mutation (SNP) | VAF 23/678 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.206); called by muse, mutect2
- TFG | c.868G>T p.G290* | Nonsense Mutation (SNP) | VAF 290/722 reads (40%) | called by muse, mutect2
- CANX | c.633G>A p.T211= | Silent (SNP) | VAF 89/896 reads (10%) | called by muse, mutect2
- DEFB112 | c.267T>A p.P89= | Silent (SNP) | VAF 26/492 reads (5%) | called by muse, mutect2
- NRAP | c.2830T>C p.L944= (on ENST00000359988 / NM_001322945.2; = p.L909= on NM_006175.4) | Silent (SNP) | VAF 205/707 reads (29%) | called by muse, mutect2, varscan2
- TIE1 | c.3237C>T p.D1079= | Silent (SNP) | VAF 83/327 reads (25%) | catalogued as rs376044375, COSV65249959; called by muse, mutect2, varscan2
- ZNF335 | c.2112C>T p.S704= | Silent (SNP) | VAF 28/482 reads (6%) | catalogued as COSV59820154; called by muse, mutect2
- ABI3BP | c.1577-16682G>A | Intron (SNP) | VAF 231/837 reads (28%) | catalogued as rs185166824, COSV52541809; called by muse, mutect2, varscan2
